Somatic mutation profile of tumor specimen 0DQHB4 from CCDI case PBCEPC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 5.9 years (2,173 days).
Specimen 0DQHB4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d4dcc45-00b3-41cb-81a7-fe373eaccb07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQHAC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/838c21b2-9b3b-468c-bd1b-2dbfa8263985

The open-access MAF lists 45 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, 3'UTR 4, Frame Shift Ins 4, 5'UTR 3, Intron 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD35 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 66/267 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs375339912, COSV62911347; called by muse, mutect2, varscan2
- DNAH6 | c.7494G>C p.K2498N | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV52882594; called by muse, mutect2, varscan2
- FOXR1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.283); catalogued as rs144436263; called by muse, mutect2, varscan2
- IL7R | c.799dup p.R267Kfs*3 | Frame Shift Ins (INS) | VAF 78/297 reads (26%) | catalogued as rs1384901919; called by mutect2, varscan2
- MATN1 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419796411; called by muse, mutect2, varscan2
- MMP15 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.122); catalogued as rs769667733; called by muse, mutect2, varscan2
- PKNOX2 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.084); catalogued as COSV100020497; called by mutect2, varscan2
- PXDNL | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs958208659, COSV100683116, COSV62493670; called by muse, mutect2
- STPG3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs760591785; called by mutect2, varscan2
- ANK1 | c.2176G>T p.D726Y | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- CADPS2 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by mutect2, varscan2
- CREBBP | c.784_790dup p.M264Rfs*20 | Frame Shift Ins (INS) | VAF 66/122 reads (54%) | called by mutect2, varscan2
- CYP2J2 | c.789C>A p.D263E | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIP1 | c.2043dup p.P682Afs*10 (on ENST00000359742 / NM_001379345.1; = p.P630Afs*10 on NM_021150.4 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 22/198 reads (11%) | called by mutect2, varscan2
- GSDMC | c.1178A>C p.K393T | Missense Mutation (SNP) | VAF 68/381 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IQSEC2 | c.572C>A p.A191E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.7); called by muse, varscan2
- IRAG1 | c.2284G>T p.A762S | Missense Mutation (SNP) | VAF 107/370 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LLGL2 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 64/283 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); called by mutect2, varscan2
- MAPRE2 | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- NXPE4 | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2W3 | c.419T>A p.L140H | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLD3 | c.1379_1382dup p.E461Dfs*16 | Frame Shift Ins (INS) | VAF 44/178 reads (25%) | called by mutect2, varscan2
- SLC26A11 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 94/294 reads (32%) | called by muse, mutect2, varscan2
- SRRT | c.1031A>G p.E344G | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TULP4 | c.1952A>T p.D651V | Missense Mutation (SNP) | VAF 90/372 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- UBAP2L | c.692A>C p.D231A | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.245); called by muse, mutect2
- ZCRB1 | c.238G>C p.V80L | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF33A | c.1207C>T p.Q403* (on ENST00000458705 / NM_006974.3; = p.Q404* on NM_006954.2) | Nonsense Mutation (SNP) | VAF 53/194 reads (27%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.4791G>T p.V1597= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as rs373660930; called by muse, mutect2, varscan2
- CUL9 | c.921C>A p.G307= | Silent (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- DEFB115 | c.126T>C p.T42= | Silent (SNP) | VAF 40/351 reads (11%) | called by muse, mutect2, varscan2
- FITM1 | c.48A>C p.R16= | Silent (SNP) | VAF 18/181 reads (10%) | called by muse, mutect2, varscan2
- NRAP | c.741C>T p.P247= | Silent (SNP) | VAF 64/256 reads (25%) | catalogued as rs148959583; called by muse, mutect2, varscan2
- OR5H15 | c.9G>A p.E3= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV62948750; called by mutect2, varscan2
- USP34 | c.1902C>A p.P634= | Silent (SNP) | VAF 84/363 reads (23%) | called by muse, mutect2, varscan2
- CLEC16A | c.1660+43G>T | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- CYP4F3 | c.*35G>T | 3'UTR (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.*24A>T | 3'UTR (SNP) | VAF 74/556 reads (13%) | called by muse, mutect2, varscan2
- EGFR | c.*48C>A | 3'UTR (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- GLCCI1 | c.-45G>T | 5'UTR (SNP) | VAF 3/19 reads (16%) | catalogued as COSV56200632; called by muse, varscan2
- PTPN9 | c.-62G>T | 5'UTR (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- RNF183 | c.-37-51C>G | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2
- SOCS5 | c.*62T>C | 3'UTR (SNP) | VAF 38/116 reads (33%) | called by muse, mutect2, varscan2
- TRPV6 | c.1640-42G>T | Intron (SNP) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- ZNF121 | c.-58G>A | 5'UTR (SNP) | VAF 85/285 reads (30%) | called by muse, mutect2, varscan2
